Somatic mutation profile of tumor specimen TCGA-95-7043-01A (aliquot TCGA-95-7043-01A-11D-1945-08) from TCGA case TCGA-95-7043, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.4 years (23,165 days).
Specimen TCGA-95-7043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e0e8e8d-425d-4046-a4c1-0ae04f7adff0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-95-7043-10A (Blood Derived Normal), aliquot TCGA-95-7043-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88431233-111a-4901-b746-4a6d25f54c95

The open-access MAF lists 1,193 somatic variants for this specimen: 919 protein-altering or splice-affecting, 249 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 777, Silent 249, Nonsense Mutation 66, Frame Shift Del 38, Splice Site 22, Frame Shift Ins 12, Intron 9, RNA 6, 3'Flank 5, Splice Region 3, 5'UTR 2, 5'Flank 2.

Variants (750 of 1,193; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4287-1G>C p.X1429_splice | Splice Site (SNP) | VAF 4/36 reads (11%) | hotspot (GDC flag); catalogued as CS162055, COSV54332253; called by muse, mutect2
- NPHS2 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs74315345, CM000580, COSV62635220, COSV62635483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 50/56 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV59386274; called by muse, mutect2, varscan2
- AARD | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as rs1458736491, COSV65599835; called by muse, mutect2, varscan2
- ABCA1 | c.3929G>T p.G1310V | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV66066122; called by muse, mutect2, varscan2
- ABCA13 | c.13136C>A p.A4379D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV68946465; called by muse, mutect2, varscan2
- ABCA5 | c.2987A>T p.N996I | Missense Mutation (SNP) | VAF 69/297 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67016747; called by muse, mutect2, varscan2
- ABCB4 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.251); catalogued as COSV55935084; called by muse, mutect2, varscan2
- ABCC11 | c.3607G>A p.G1203S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs769368539, COSV62322938; called by muse, mutect2, varscan2
- ABCC8 | c.2255G>A p.S752N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV56850146; called by muse, mutect2, varscan2
- ABCG5 | c.534C>G p.S178R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.549); catalogued as COSV53210671; called by muse, mutect2, varscan2
- ABHD10 | c.376A>T p.T126S | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as COSV56325078; called by muse, mutect2, varscan2
- ABRA | c.8del p.P3Rfs*122 | Frame Shift Del (DEL) | VAF 30/51 reads (59%) | catalogued as COSV100357675; called by mutect2, pindel, varscan2
- AC006059.2 | c.1895C>A p.P632Q | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV59606829; called by muse, mutect2, varscan2
- AC127029.3 | c.806C>A p.S269* | Nonsense Mutation (SNP) | VAF 99/145 reads (68%) | catalogued as COSV100033231, COSV60110868; called by muse, mutect2, varscan2
- ACD | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1475506303, COSV54667539; called by muse, mutect2, varscan2
- ACSL1 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 164/201 reads (82%) | catalogued as COSV55662521; called by muse, mutect2, varscan2
- ACTB | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV59318376; called by muse, mutect2, varscan2
- ACTL7B | c.857del p.G286Afs*74 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | catalogued as COSV65927215; called by mutect2, pindel, varscan2
- ADAM2 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV55861884; called by muse, mutect2
- ADAMTS14 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV64601849; called by muse, mutect2, varscan2
- ADAMTS7 | c.3269G>A p.G1090E | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV66307122; called by muse, mutect2
- ADAMTSL3 | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV54446945; called by muse, mutect2, varscan2
- ADGRB3 | c.3555G>T p.M1185I | Missense Mutation (SNP) | VAF 32/37 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV53243570; called by muse, mutect2, varscan2
- ADGRG5 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs373284862; called by muse, mutect2, varscan2
- ADGRV1 | c.15971G>T p.G5324V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV67984768; called by muse, mutect2, varscan2
- ADH5 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56448106; called by muse, mutect2, varscan2
- AFF2 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 276/388 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60664320; called by muse, mutect2, varscan2
- AFF2 | c.1997C>A p.P666Q | Missense Mutation (SNP) | VAF 142/209 reads (68%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV53988417; called by muse, mutect2, varscan2
- AFF2 | c.2533G>C p.E845Q | Missense Mutation (SNP) | VAF 72/119 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV53988446, COSV99665708; called by muse, mutect2, varscan2
- AGMO | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV61111986; called by muse, mutect2, varscan2
- AHNAK2 | c.11753C>A p.P3918H | Missense Mutation (SNP) | VAF 170/200 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV60914878; called by mutect2, varscan2
- AIFM1 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 104/184 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54854500; called by muse, mutect2, varscan2
- AKAP4 | c.2467C>A p.Q823K | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV62074379, COSV62074461; called by muse, mutect2, varscan2
- AKT3 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV55615787; called by muse, mutect2, varscan2
- ALG10 | c.1216G>T p.V406F | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as COSV56792501; called by muse, mutect2, varscan2
- AMER1 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV57660371; called by muse, mutect2, varscan2
- AMER3 | c.1220C>T p.T407I | Missense Mutation (SNP) | VAF 49/52 reads (94%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.844); catalogued as rs1344052778, COSV58466623; called by muse, mutect2, varscan2
- AMER3 | c.1987G>T p.G663* | Nonsense Mutation (SNP) | VAF 17/18 reads (94%) | catalogued as rs777912797, COSV58466629, COSV58470366; called by muse, mutect2, varscan2
- ANKRD17 | c.4287G>T p.E1429D | Missense Mutation (SNP) | VAF 44/53 reads (83%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.956); catalogued as COSV58219720; called by muse, mutect2, varscan2
- ANKS1B | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.76); PolyPhen benign (0.012); catalogued as COSV61350027; called by muse, mutect2, varscan2
- ANO5 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV61084743; called by muse, mutect2, varscan2
- ANO5 | c.2224G>A p.V742I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV61084749; called by muse, mutect2, varscan2
- ANO7 | c.411C>A p.H137Q (on ENST00000274979; = p.H82Q on NM_001001666.4) | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV51471492; called by muse, mutect2, varscan2
- AOAH | c.835C>A p.Q279K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.381); catalogued as COSV51740809; called by muse, varscan2
- AP002512.3 | c.1066G>T p.G356W | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99687678, COSV99688109; called by muse, mutect2, varscan2
- AP002512.3 | c.1065T>A p.Y355* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as COSV99688111; called by muse, mutect2, varscan2
- AP002512.3 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1443157134, COSV54406571; called by muse, mutect2, varscan2
- APC2 | c.1715G>A p.C572Y | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52018217; called by muse, mutect2, varscan2
- APCDD1 | c.662A>G p.H221R | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1448686079, COSV62372457; called by muse, mutect2, varscan2
- APOA5 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1434092204, COSV57063116; called by muse, mutect2, varscan2
- APOL6 | c.604A>C p.K202Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68749492; called by muse, mutect2, varscan2
- AQP8 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.799); catalogued as COSV54845177; called by muse, mutect2, varscan2
- ARAP1 | c.2635G>T p.A879S (on ENST00000393609 / NM_001040118.2; = p.A634S on NM_015242.4) | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.96); PolyPhen benign (0.01); catalogued as COSV100502159; called by muse, varscan2
- ARHGAP4 | c.1843G>T p.E615* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV61686180; called by muse, mutect2, varscan2
- ARHGEF10 | c.1515G>T p.S505= (on ENST00000398564; = p.S480= on NM_014629.4) | Splice Region (SNP) | VAF 12/13 reads (92%) | catalogued as COSV50648933; called by muse, mutect2, varscan2
- ARIH1 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV65911529; called by muse, mutect2, varscan2
- ARMCX5 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 68/136 reads (50%) | catalogued as COSV55766535; called by muse, varscan2
- ARMCX5 | c.874G>T p.G292W | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55766539; called by muse, varscan2
- ARRB1 | c.982G>T p.V328L | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.189); catalogued as COSV63575400; called by muse, varscan2
- ASB17 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV52410295; called by muse, mutect2, varscan2
- ASRGL1 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57124544; called by muse, mutect2, varscan2
- ASTN1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV56068451; called by muse, mutect2, varscan2
- ASTN1 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56068461; called by muse, varscan2
- ASTN2 | c.1675G>A p.G559R (on ENST00000313400 / NM_001365069.1; = p.G508R on NM_014010.5) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100525292, COSV57775594; called by muse, mutect2, varscan2
- ASXL3 | c.2471C>G p.P824R | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV52459496, COSV52465227; called by muse, mutect2, varscan2
- ATP2B2 | c.2219G>T p.G740V (on ENST00000352432; = p.G706V on NM_001683.5) | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59495935; called by muse, mutect2, varscan2
- ATP2B3 | c.1616T>C p.V539A | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV54846644; called by muse, mutect2, varscan2
- ATP2C1 | c.1655T>C p.V552A | Missense Mutation (SNP) | VAF 80/92 reads (87%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as COSV60756040; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2455G>T p.G819C (on ENST00000343619 / NM_001378531.1; = p.G813C on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52873205, COSV52876073; called by muse, mutect2, varscan2
- ATP6V1C1 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67777972; called by muse, mutect2, varscan2
- ATP7A | c.2029C>A p.H677N | Missense Mutation (SNP) | VAF 169/299 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.346); catalogued as COSV58445989; called by muse, varscan2
- ATP9A | c.1620G>C p.Q540H | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV58766280; called by muse, mutect2, varscan2
- ATRNL1 | c.3667C>A p.Q1223K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV58087073; called by muse, mutect2, varscan2
- ATRNL1 | c.3862G>A p.V1288M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.172); catalogued as COSV58087078; called by muse, mutect2
- ATRX | c.1945G>T p.E649* | Nonsense Mutation (SNP) | VAF 205/350 reads (59%) | catalogued as COSV64876239, COSV64876874; called by muse, mutect2, varscan2
- AUTS2 | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.87); PolyPhen benign (0.022); catalogued as COSV61399767; called by muse, mutect2
- AUTS2 | c.2116G>T p.A706S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs764564016, COSV61399781; called by muse, mutect2, varscan2
- AXDND1 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62640170, COSV62642393; called by muse, mutect2, varscan2
- BCL9L | c.1247A>T p.D416V | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52684187; called by muse, mutect2, varscan2
- BICD2 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV63548935, COSV63550067; called by muse, mutect2, varscan2
- BICRA | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV67604718; called by muse, mutect2, varscan2
- BIRC2 | c.1366+1G>T p.X456_splice | Splice Site (SNP) | VAF 20/34 reads (59%) | catalogued as COSV57161351; called by muse, mutect2, varscan2
- BMPER | c.1164C>A p.Y388* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV51817915; called by muse, mutect2, varscan2
- BMT2 | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV51776542; called by muse, mutect2, varscan2
- BPIFB3 | c.1309G>C p.A437P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV64957306; called by muse, mutect2, varscan2
- BRAT1 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV61395230; called by muse, mutect2, varscan2
- BRD3 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV57703587, COSV57704581; called by muse, mutect2, varscan2
- BRWD3 | c.2707C>A p.Q903K | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV64747697; called by muse, mutect2, varscan2
- BSN | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV56517487; called by muse, mutect2, varscan2
- BTBD16 | c.1490T>G p.V497G | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV53262857; called by muse, mutect2, varscan2
- BTN3A1 | c.1077G>T p.Q359H | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV50024780; called by muse, mutect2, varscan2
- C10orf120 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 17/37 reads (46%) | catalogued as COSV61491918, COSV61491926; called by muse, mutect2, varscan2
- C19orf73 | c.98A>T p.H33L | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.01); catalogued as COSV55521552; called by muse, mutect2, varscan2
- C2orf16 | c.2213C>T p.T738I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV62675422; called by muse, mutect2, varscan2
- C5orf38 | c.303G>T p.R101S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57411089; called by muse, mutect2, varscan2
- C6orf118 | c.894C>A p.Y298* | Nonsense Mutation (SNP) | VAF 14/18 reads (78%) | catalogued as COSV57814809; called by muse, mutect2, varscan2
- C7 | c.2280G>T p.R760S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57474055; called by muse, mutect2, varscan2
- C8orf74 | c.358C>A p.R120S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as COSV100262349, COSV100262420; called by muse, mutect2, varscan2
- CABLES1 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as COSV56933038; called by muse, mutect2, varscan2
- CACNA1B | c.6592C>A p.R2198S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53125203; called by muse, mutect2, varscan2
- CALHM1 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61707525; called by muse, mutect2, varscan2
- CALHM2 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53295644; called by muse, mutect2, varscan2
- CAMKK1 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 38/50 reads (76%) | catalogued as COSV50116503; called by muse, mutect2, varscan2
- CAND1 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 63/71 reads (89%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV73389603; called by muse, mutect2, varscan2
- CASP9 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.215); catalogued as COSV61601425; called by muse, mutect2, varscan2
- CBLIF | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV57238849; called by muse, mutect2, varscan2
- CCDC134 | c.54G>T p.M18I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV55387986; called by muse, mutect2, varscan2
- CCDC144A | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as COSV100138670; called by muse, mutect2, varscan2
- CCDC18 | c.3078G>T p.Q1026H (on ENST00000343253 / NM_001306076.1; = p.Q1027H on NM_206886.4) | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58143281; called by muse, mutect2, varscan2
- CCDC40 | c.3332T>C p.L1111P | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56408460; called by muse, mutect2, varscan2
- CCDC73 | c.1822C>A p.P608T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.215); catalogued as COSV58798211; called by muse, mutect2, varscan2
- CCDC85A | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.444); catalogued as COSV68150423; called by muse, mutect2, varscan2
- CCER1 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 39/51 reads (76%) | catalogued as COSV62646766; called by muse, mutect2, varscan2
- CCL28 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.902); catalogued as COSV63149322, COSV63150163; called by muse, mutect2, varscan2
- CCL28 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63149329; called by muse, mutect2, varscan2
- CCN4 | c.263C>A p.T88K | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV51531488; called by muse, mutect2, varscan2
- CCNA1 | c.944C>A p.T315N | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55221368; called by muse, mutect2, varscan2
- CD33 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.114); catalogued as COSV51801707; called by muse, mutect2, varscan2
- CD44 | c.1303C>A p.H435N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV53529262; called by muse, mutect2, varscan2
- CD8B | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58926033; called by muse, mutect2, varscan2
- CDC42BPG | c.580A>T p.R194W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61347329; called by muse, mutect2
- CDH10 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52580080; called by muse, mutect2, varscan2
- CDH12 | c.1493G>T p.C498F | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66403580; called by muse, mutect2, varscan2
- CDH22 | c.747C>A p.D249E | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV64837476; called by muse, mutect2, varscan2
- CDH26 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); catalogued as COSV54846648; called by muse, mutect2, varscan2
- CDH4 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV64653769; called by muse, mutect2, varscan2
- CDH5 | c.598T>A p.F200I | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58517399; called by muse, mutect2, varscan2
- CDH6 | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as rs1239863031, COSV54067402; called by muse, mutect2, varscan2
- CELSR3 | c.5665G>T p.G1889C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50857587; called by muse, mutect2, varscan2
- CFAP91 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 72/79 reads (91%) | SIFT tolerated (0.34); PolyPhen benign (0.106); catalogued as COSV56340858; called by muse, mutect2, varscan2
- CFHR3 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV66402118, COSV66402854; called by muse, mutect2, varscan2
- CHCHD3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52774338; called by muse, mutect2, varscan2
- CIT | c.3212A>T p.E1071V | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55868022; called by muse, mutect2, varscan2
- CLC | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs756972983, COSV55685242; called by muse, mutect2, varscan2
- CLCA4 | c.1231C>A p.L411M | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV55368025; called by muse, mutect2, varscan2
- CLDN8 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54525871; called by muse, mutect2, varscan2
- CLEC14A | c.959C>A p.P320Q | Missense Mutation (SNP) | VAF 67/82 reads (82%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.279); catalogued as COSV60562460; called by muse, mutect2, varscan2
- CLEC4G | c.677G>T p.R226M | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61003263; called by muse, mutect2, varscan2
- CLIC6 | c.2035A>G p.R679G (on ENST00000360731 / NM_001317009.2; = p.R661G on NM_053277.3) | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62447629; called by muse, mutect2, varscan2
- CLIP3 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV62112458; called by muse, mutect2, varscan2
- CLSTN2 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71720712; called by muse, mutect2, varscan2
- CLVS1 | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.48); PolyPhen benign (0.115); catalogued as COSV57973435, COSV57974509; called by muse, mutect2, varscan2
- CNNM1 | c.2378G>C p.C793S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63201477; called by muse, mutect2, varscan2
- CNTN3 | c.1946-1G>T p.X649_splice | Splice Site (SNP) | VAF 29/39 reads (74%) | catalogued as COSV55170600; called by muse, mutect2, varscan2
- CNTNAP2 | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV62177661; called by muse, mutect2, varscan2
- COL11A1 | c.5002C>A p.P1668T | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62182879; called by muse, mutect2, varscan2
- COL12A1 | c.8471G>T p.G2824V | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59395519, COSV59411217; called by muse, mutect2, varscan2
- COL12A1 | c.5338G>T p.V1780L | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as COSV59395524; called by muse, mutect2, varscan2
- COL13A1 | c.521C>G p.P174R (on ENST00000398978 / NM_001130103.2; = p.P136R on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62569109, COSV62569645; called by muse, mutect2, varscan2
- COL1A2 | c.3988G>C p.E1330Q | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51957655, COSV99799861; called by muse, mutect2, varscan2
- COL20A1 | c.1218G>T p.K406N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100491356; called by muse, mutect2, varscan2
- COL24A1 | c.744C>A p.Y248* | Nonsense Mutation (SNP) | VAF 36/44 reads (82%) | catalogued as COSV65305858; called by muse, varscan2
- COL27A1 | c.3403G>T p.G1135* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV61925793; called by muse, mutect2, varscan2
- COL4A2 | c.3083G>T p.R1028M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); catalogued as COSV64628037; called by muse, mutect2, varscan2
- COL4A6 | c.4549C>A p.P1517T | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57866000; called by muse, mutect2, varscan2
- COL6A2 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.82); PolyPhen benign (0.156); catalogued as rs746541506, COSV56004369; called by muse, mutect2, varscan2
- COL6A3 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 69/76 reads (91%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV55088702; called by muse, mutect2, varscan2
- COLEC10 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60521227, COSV60521521; called by muse, mutect2, varscan2
- COLEC12 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs200501360; called by muse, mutect2, varscan2
- CPE | c.242G>C p.R81P | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV68580178, COSV68580955; called by muse, mutect2
- CPNE3 | c.1561A>G p.T521A | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV52206188; called by muse, mutect2, varscan2
- CPT1A | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55755821, COSV99680645; called by muse, mutect2, varscan2
- CPXCR1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.031); catalogued as COSV52161514; called by muse, mutect2, varscan2
- CRB2 | c.1897C>G p.R633G | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs730880377, CM150102, COSV63503068, COSV63503306; called by muse, mutect2, varscan2
- CRHBP | c.474G>T p.M158I | Missense Mutation (SNP) | VAF 22/31 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57188479, COSV57189966; called by muse, mutect2, varscan2
- CRIM1 | c.968G>T p.C323F | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54863650; called by muse, mutect2, varscan2
- CRLF1 | c.1265G>C p.R422T | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV62260679; called by muse, varscan2
- CRLF1 | c.480C>A p.H160Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV66504517; called by muse, mutect2, varscan2
- CSMD3 | c.10829G>T p.G3610V (on ENST00000297405 / NM_001363185.1; = p.G3441V on NM_052900.3) | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV52173741, COSV99832631; called by muse, mutect2, varscan2
- CSMD3 | c.10441C>A p.L3481M (on ENST00000297405 / NM_001363185.1; = p.L3312M on NM_052900.3) | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.293); catalogued as COSV52173762; called by muse, mutect2, varscan2
- CSMD3 | c.7108C>G p.L2370V (on ENST00000297405 / NM_001363185.1; = p.L2266V on NM_052900.3) | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52148172, COSV52173782; called by muse, mutect2, varscan2
- CSMD3 | c.2182C>A p.P728T (on ENST00000297405 / NM_001363185.1; = p.P624T on NM_052900.3) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV104398493, COSV52173818; called by muse, mutect2, varscan2
- CSMD3 | c.709+1G>T p.X237_splice | Splice Site (SNP) | VAF 37/51 reads (73%) | catalogued as COSV52173836; called by muse, mutect2, varscan2
- CSN1S1 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.23); PolyPhen benign (0.103); catalogued as COSV55890500; called by muse, mutect2, varscan2
- CSNK1G1 | c.680-1G>A p.X227_splice | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100274228, COSV57309565; called by muse, mutect2, varscan2
- CSNK1G3 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62054454; called by muse, mutect2, varscan2
- CTDP1 | c.2571G>T p.M857I | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50003107; called by muse, mutect2, varscan2
- CUL3 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52364592; called by muse, mutect2, varscan2
- CXorf66 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 113/181 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65169228, COSV65169640; called by muse, mutect2, varscan2
- CYLC1 | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV61411943, COSV61412298, COSV61416610; called by muse, mutect2, varscan2
- CYP11B1 | c.1196C>G p.A399G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52826957; called by muse, mutect2, varscan2
- DCC | c.2040G>T p.W680C | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV59097994, COSV59101087; called by muse, mutect2, varscan2
- DCC | c.4012C>A p.P1338T | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1250355443, COSV71431648; called by muse, mutect2, varscan2
- DCHS1 | c.2609G>C p.G870A | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55035237; called by muse, mutect2, varscan2
- DCHS1 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as rs146159630; called by muse, mutect2, varscan2
- DDI1 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56377390; called by muse, mutect2, varscan2
- DENND4A | c.2587A>G p.R863G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV71265720; called by muse, mutect2, varscan2
- DGKG | c.1214G>A p.R405K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs762619489, COSV53964862; called by muse, mutect2, varscan2
- DHRSX | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 66/86 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58133384; called by muse, mutect2, varscan2
- DHX37 | c.1961C>A p.S654Y | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs759207005, COSV58134326, COSV58134359; called by muse, mutect2, varscan2
- DHX57 | c.723G>T p.L241F | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV54885092; called by muse, mutect2, varscan2
- DIAPH2 | c.1717G>C p.G573R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61268916, COSV61278112, COSV61282411; called by muse, mutect2, varscan2
- DIDO1 | c.4699G>C p.A1567P | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as COSV56621718; called by muse, mutect2, varscan2
- DIO3 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (0.2); PolyPhen benign (0.352); catalogued as rs764206516, COSV100832115, COSV63773587; called by muse, mutect2, varscan2
- DLG2 | c.1414G>T p.G472C | Missense Mutation (SNP) | VAF 36/55 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV54642409; called by muse, mutect2, varscan2
- DLX5 | c.368C>A p.T123N | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56032444; called by muse, mutect2, varscan2
- DMD | c.603C>A p.N201K | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as rs750180929, COSV55869322; called by muse, mutect2, varscan2
- DMD | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55869345, COSV55873503; called by muse, mutect2, varscan2
- DNAH3 | c.7354G>T p.A2452S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV54520286, COSV99771160; called by muse, mutect2, varscan2
- DNAH9 | c.9275C>A p.A3092D | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.36); PolyPhen benign (0.033); catalogued as COSV52348468; called by muse, mutect2, varscan2
- DNAJC10 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as rs902227509, COSV51137978; called by muse, mutect2, varscan2
- DNHD1 | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1228846057, COSV54435267; called by muse, mutect2, varscan2
- DOCK2 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV56956974; called by muse, mutect2, varscan2
- DOCK4 | c.2055C>A p.Y685* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV70236350, COSV70236489; called by muse, mutect2, varscan2
- DOCK9 | c.3869G>T p.R1290L (on ENST00000376460 / NM_001366676.2; = p.R1291L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV59625565, COSV59628424; called by muse, mutect2, varscan2
- DRC7 | c.979A>T p.S327C | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61054531; called by muse, mutect2, varscan2
- DRD2 | c.475G>C p.V159L | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60757690; called by muse, mutect2
- DROSHA | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.06); catalogued as COSV60775736; called by muse, mutect2, varscan2
- DSN1 | c.633G>A p.M211I | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV65519126; called by muse, mutect2, varscan2
- DSP | c.2055G>T p.R685S | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65792590; called by muse, mutect2, varscan2
- DUOXA1 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV50993504; called by muse, mutect2, varscan2
- DYNC2H1 | c.10086C>A p.Y3362* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV62093597; called by muse, mutect2, varscan2
- DYSF | c.2885G>T p.G962V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV50317221; called by muse, varscan2
- E2F7 | c.370-2A>T p.X124_splice | Splice Site (SNP) | VAF 19/24 reads (79%) | catalogued as COSV59739571; called by muse, mutect2, varscan2
- EBI3 | c.368C>A p.T123K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55690133; called by muse, mutect2, varscan2
- ECI2 | c.706A>T p.K236* (on ENST00000380118 / NM_206836.3; = p.K206* on NM_006117.2) | Nonsense Mutation (SNP) | VAF 34/40 reads (85%) | catalogued as COSV60986328; called by muse, mutect2, varscan2
- ELL | c.1065G>T p.K355N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); catalogued as COSV99443701; called by muse, mutect2, varscan2
- EMD | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 89/130 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63962166; called by muse, mutect2, varscan2
- EMILIN2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54423410; called by muse, mutect2, varscan2
- ENGASE | c.1143-2A>T p.X381_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV56135387; called by muse, mutect2
- EOMES | c.1543C>A p.P515T | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as COSV55412384, COSV55413869; called by muse, mutect2, varscan2
- EPAS1 | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV55386379, COSV55386613; called by muse, mutect2, varscan2
- EPHA2 | c.2785G>T p.G929C | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64453053, COSV64454563; called by muse, mutect2, varscan2
- EPHB6 | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV67418473; called by muse, mutect2, varscan2
- EPHX1 | c.1245C>A p.F415L | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55300534; called by muse, mutect2, varscan2
- ERICH3 | c.704C>A p.P235H | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58606137; called by muse, mutect2, varscan2
- ERN1 | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV70502069; called by muse, mutect2, varscan2
- ERN2 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56833553; called by muse, mutect2, varscan2
- ERRFI1 | c.1154A>T p.N385I | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV66310649; called by muse, mutect2, varscan2
- ESR1 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV52790184; called by muse, mutect2, varscan2
- EXO1 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 47/52 reads (90%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV62217434, COSV62219521; called by muse, mutect2, varscan2
- EXOC4 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs780930711, COSV54096953; called by muse, mutect2, varscan2
- EYA4 | c.1358G>T p.S453I (on ENST00000531901 / NM_001301013.1; = p.S447I on NM_004100.5) | Missense Mutation (SNP) | VAF 50/65 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62051470; called by muse, mutect2, varscan2
- EYA4 | c.1715G>C p.G572A (on ENST00000531901 / NM_001301013.1; = p.G566A on NM_004100.5) | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV62051485; called by muse, mutect2, varscan2
- F2 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as COSV61315719; called by muse, mutect2, varscan2
- F2R | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59929072; called by muse, mutect2, varscan2
- F8 | c.3898G>T p.G1300* | Nonsense Mutation (SNP) | VAF 45/187 reads (24%) | catalogued as COSV64273229; called by muse, mutect2, varscan2
- FAM131B | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68126003; called by muse, mutect2, varscan2
- FAM133A | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59075178; called by muse, mutect2, varscan2
- FAM170A | c.355G>T p.V119L | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV58925054; called by muse, mutect2, varscan2
- FAM219A | c.257G>T p.R86L (on ENST00000445726; = p.R69L on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs777204338, COSV52620704, COSV52621205; called by muse, mutect2, varscan2
- FAM221A | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1412434811, COSV61387752; called by muse, mutect2
- FAM227B | c.875-1G>A p.X292_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV54810253; called by muse, mutect2, varscan2
- FAM47A | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV60496448; called by muse, mutect2, varscan2
- FAM71B | c.1403G>C p.R468P | Missense Mutation (SNP) | VAF 62/78 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV57229026; called by muse, mutect2, varscan2
- FAM83C | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.138); catalogued as COSV65582974; called by muse, mutect2, varscan2
- FARS2 | c.206A>T p.K69M | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV51166968; called by muse, mutect2, varscan2
- FAT3 | c.12763G>T p.G4255W | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV53107381, COSV53122947; called by muse, mutect2, varscan2
- FCRL4 | c.1102G>T p.V368F | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54862040; called by muse, mutect2, varscan2
- FCRL5 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs769954572, COSV62514287; called by muse, mutect2, varscan2
- FER | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55290516; called by muse, mutect2, varscan2
- FER1L6 | c.3019G>T p.V1007L | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV67549745; called by muse, mutect2, varscan2
- FEZ1 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV54028473; called by muse, mutect2, varscan2
- FFAR3 | c.365G>A p.W122* | Nonsense Mutation (SNP) | VAF 30/144 reads (21%) | catalogued as COSV100588298; called by muse, mutect2, varscan2
- FGD5 | c.1459G>T p.G487W | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53242356; called by muse, mutect2, varscan2
- FGF13 | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV65434537; called by muse, mutect2, varscan2
- FKBP6 | c.568G>T p.A190S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52720105; called by muse, mutect2, varscan2
- FKBP6 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV52720128, COSV52720387; called by muse, mutect2, varscan2
- FLG | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 185/526 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV64236707, COSV64241574; called by muse, mutect2, varscan2
- FLNA | c.4366C>A p.P1456T | Missense Mutation (SNP) | VAF 195/321 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV61042592; called by muse, mutect2, varscan2
- FLNA | c.2848A>C p.T950P | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV61042606; called by muse, mutect2, varscan2
- FLNC | c.6862G>T p.V2288F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100368658; called by muse, mutect2
- FMO3 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145526965, COSV100882415; called by muse, varscan2
- FMR1 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV54423677; called by muse, mutect2, varscan2
- FMR1 | c.1606G>A p.G536R | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (1); catalogued as COSV99503749; called by muse, mutect2, varscan2
- FMR1 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1242465710, COSV99503750; called by muse, mutect2, varscan2
- FNDC1 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 6/8 reads (75%) | catalogued as COSV51937308, COSV51942999; called by mutect2, varscan2
- FNDC1 | c.5301G>A p.W1767* | Nonsense Mutation (SNP) | VAF 18/22 reads (82%) | catalogued as COSV51932123; called by muse, mutect2, varscan2
- FNDC11 | c.806A>T p.D269V | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV64442762; called by muse, mutect2, varscan2
- FOXP1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV59538934, COSV59541716; called by muse, mutect2, varscan2
- FRG1 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 75/87 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56995675, COSV57000707; called by muse, mutect2, varscan2
- FRMD7 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV53746073; called by muse, mutect2, varscan2
- FSTL4 | c.1587C>G p.I529M | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV54770126; called by muse, mutect2, varscan2
- FTMT | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV58420228, COSV58420991; called by muse, mutect2, varscan2
- FTO | c.311G>T p.C104F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.179); catalogued as COSV67111562; called by muse, mutect2, varscan2
- FZD4 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.939); catalogued as rs777565148, COSV72294254, COSV72294375; called by muse, mutect2, varscan2
- GABRA6 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV50880724; called by muse, mutect2, varscan2
- GABRD | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs751411266, COSV66080509; called by muse, mutect2, varscan2
- GABRG1 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1044894268, COSV54953751; called by muse, mutect2, varscan2
- GALNT15 | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV60216912; called by muse, mutect2, varscan2
- GALNT6 | c.1294G>T p.A432S | Missense Mutation (SNP) | VAF 112/141 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62542146; called by muse, mutect2, varscan2
- GATAD2B | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs1056350674, COSV64084063; called by muse, mutect2, varscan2
- GCOM1 | c.193A>G p.R65G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs377330516; called by muse, mutect2, varscan2
- GDA | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 38/42 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52992930; called by muse, mutect2, varscan2
- GIMAP4 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1450572705, COSV55432273, COSV55434461; called by muse, mutect2, varscan2
- GLDC | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100394305, COSV58679744; called by muse, mutect2, varscan2
- GLI2 | c.3201G>C p.Q1067H (on ENST00000361492 / NM_001374353.1; = p.Q1084H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV58041479; called by muse, mutect2, varscan2
- GLRA2 | c.715G>A p.G239R | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54340284; called by muse, mutect2, varscan2
- GLRA4 | c.963G>T p.W321C | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60327632; called by muse, mutect2, varscan2
- GMPPA | c.1055G>C p.R352P | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58006444, COSV58006861; called by muse, mutect2
- GP2 | c.158C>A p.T53N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100221564, COSV56893919; called by muse, mutect2, varscan2
- GPI | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV62893939; called by muse, mutect2, varscan2
- GPR139 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); catalogued as COSV58501867, COSV58502788; called by muse, mutect2, varscan2
- GPR141 | c.653A>T p.H218L | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57732171; called by muse, mutect2, varscan2
- GPR158 | c.1514G>T p.R505M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66269630, COSV66281948; called by muse, varscan2
- GPR158 | c.2543C>T p.T848I | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1429504834, COSV66269634; called by muse, mutect2, varscan2
- GPR161 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.081); catalogued as COSV54789976; called by muse, mutect2, varscan2
- GPR174 | c.713T>A p.V238E | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52132429; called by muse, mutect2, varscan2
- GPR32 | c.832G>C p.V278L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV54514448; called by muse, mutect2, varscan2
- GPR50 | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 140/215 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs372712912, COSV54438881, COSV99506217; called by muse, mutect2, varscan2
- GPR50 | c.1390T>A p.S464T | Missense Mutation (SNP) | VAF 527/745 reads (71%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV54438895; called by muse, mutect2, varscan2
- GPRC5B | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.239); catalogued as rs1324150374, COSV56026404; called by muse, mutect2, varscan2
- GPRC6A | c.1437G>A p.W479* | Nonsense Mutation (SNP) | VAF 44/55 reads (80%) | catalogued as COSV59952929; called by muse, mutect2, varscan2
- GPSM1 | c.918G>T p.E306D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV61304030; called by muse, mutect2, varscan2
- GPSM2 | c.24G>T p.M8I | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.838); catalogued as COSV51442390; called by muse, mutect2, varscan2
- GREB1 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.487); catalogued as COSV52186645; called by muse, mutect2, varscan2
- GREB1 | c.2173C>G p.L725V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52186664; called by muse, mutect2, varscan2
- GREB1 | c.5790C>G p.F1930L | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs774393314, COSV52186671; called by muse, mutect2, varscan2
- GRHL2 | c.1612G>T p.V538L | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as COSV52548167, COSV52556392; called by muse, mutect2, varscan2
- GRIA3 | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 114/371 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52058546; called by muse, mutect2, varscan2
- GRIK3 | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 75/95 reads (79%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV66139532; called by muse, mutect2, varscan2
- GRIK4 | c.2155G>T p.A719S | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70802144; called by muse, mutect2, varscan2
- GRM1 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268648; called by muse, mutect2, varscan2
- GRM1 | c.617C>G p.P206R | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99268655; called by muse, mutect2, varscan2
- GRM8 | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV58824111; called by muse, mutect2, varscan2
- GTF3C1 | c.4844A>T p.D1615V | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV62241101; called by muse, mutect2, varscan2
- GTPBP1 | c.1825G>T p.G609C | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1299271496, COSV53284590; called by muse, mutect2, varscan2
- GYG2 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.58); PolyPhen benign (0.215); catalogued as COSV58550077; called by muse, mutect2, varscan2
- GYS2 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.971); catalogued as COSV53923035; called by muse, mutect2, varscan2
- H6PD | c.1940C>A p.P647H | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66230978; called by muse, mutect2, varscan2
- HAVCR1 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV59399682; called by muse, mutect2, varscan2
- HCN3 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | catalogued as COSV64233974; called by muse, mutect2, varscan2
- HCN4 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs748074312, COSV56083426; called by muse, mutect2
- HCN4 | c.2136C>A p.D712E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as COSV56081881; called by muse, mutect2
- HECA | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV62769275; called by muse, mutect2, varscan2
- HELLS | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV53296803; called by muse, mutect2, varscan2
- HEPACAM2 | c.1286G>A p.R429K (on ENST00000394468 / NM_001039372.4; = p.R417K on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59060271; called by muse, mutect2, varscan2
- HEPH | c.1066G>A p.G356S (on ENST00000343002; = p.G89S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV57963484; called by muse, mutect2, varscan2
- HEPH | c.3135C>A p.H1045Q (on ENST00000343002; = p.H778Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57963505; called by muse, mutect2, varscan2
- HERC2 | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55322650; called by muse, mutect2, varscan2
- HHAT | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 49/55 reads (89%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs376601925; called by muse, mutect2, varscan2
- HIF3A | c.1528A>G p.R510G (on ENST00000377670 / NM_152795.4; = p.R441G on NM_022462.4) | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV52198205; called by muse, mutect2, varscan2
- HIPK3 | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57562087, COSV57562407; called by muse, mutect2, varscan2
- HIVEP3 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56015106; called by muse, mutect2, varscan2
- HMCN1 | c.11257C>A p.L3753I | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54898706, COSV54947961; called by muse, mutect2, varscan2
- HOXB3 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs189100448; called by muse, mutect2, varscan2
- HOXB9 | c.334G>T p.G112C | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.722); catalogued as COSV60817076; called by muse, mutect2
- HRNR | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 116/229 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769962080, COSV64256820; called by muse, mutect2, varscan2
- HS6ST3 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.838); catalogued as rs368419692; called by muse, mutect2, varscan2
- HSF2 | c.973A>T p.S325C | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV63773871; called by muse, mutect2, varscan2
- HSF5 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV60200394; called by muse, mutect2, varscan2
- HTN1 | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as rs779831486, COSV55894863; called by muse, mutect2, varscan2
- HTR2A | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV66327242; called by muse, varscan2
- HTR3A | c.904A>T p.T302S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1456981007, COSV55469118; called by muse, mutect2, varscan2
- HTR3A | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55469130; called by muse, mutect2, varscan2
- HTR3A | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.257); catalogued as COSV55469141; called by muse, mutect2, varscan2
- IGDCC3 | c.114C>A p.H38Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as COSV60077490; called by muse, mutect2, varscan2
- IGF2BP1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs1254463789, COSV51731123; called by muse, mutect2, varscan2
- IGFLR1 | c.891del p.F298Lfs*5 | Frame Shift Del (DEL) | VAF 25/57 reads (44%) | catalogued as COSV99495421; called by mutect2, pindel, varscan2
- IGHV1-2 | c.219C>G p.N73K | Missense Mutation (SNP) | VAF 128/152 reads (84%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs182499214; called by muse, mutect2, varscan2
- IGHV3-23 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 175/374 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as rs782235551; called by muse, mutect2, varscan2
- IGKV2-30 | c.170A>C p.Y57S | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs564770780; called by muse, mutect2
- IL11RA | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV52405225; called by muse, varscan2
- IL6R | c.997G>C p.A333P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.36); catalogued as COSV59816443; called by muse, mutect2, varscan2
- IL6ST | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV61141121; called by muse, mutect2, varscan2
- ILF3 | c.1850A>T p.K617M | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.737); catalogued as COSV51557309; called by muse, mutect2, varscan2
- INO80 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV62737965, COSV62743139; called by muse, mutect2, varscan2
- INS | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as CM074283, COSV99171162; called by muse, varscan2
- INSL5 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.522); catalogued as COSV58788198; called by muse, mutect2, varscan2
- IQCA1 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV54501439, COSV54513752; called by muse, mutect2, varscan2
- IRS1 | c.1270G>A p.G424S | Missense Mutation (SNP) | VAF 68/79 reads (86%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs768932529, COSV59333452, COSV59336216; called by muse, mutect2, varscan2
- IRX1 | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV57359390; called by muse, mutect2, varscan2
- ITGA8 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1203176821, COSV65228510; called by muse, mutect2
- ITGAM | c.2830G>T p.A944S (on ENST00000648685 / NM_001145808.2; = p.A943S on NM_000632.4) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.499); catalogued as COSV54936925; called by muse, mutect2
- ITGB5 | c.163G>T p.G55* | Nonsense Mutation (SNP) | VAF 39/59 reads (66%) | catalogued as COSV56148870; called by muse, mutect2, varscan2
- ITIH6 | c.3598C>G p.R1200G | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.202); catalogued as COSV54486388, COSV54488823; called by muse, mutect2
- JPH3 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV52467426; called by muse, mutect2, varscan2
- JUP | c.2023C>A p.H675N | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60277945; called by muse, mutect2, varscan2
- KAT14 | c.1387G>T p.V463L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66607629; called by muse, mutect2, varscan2
- KATNBL1 | c.141G>T p.L47F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV56623245; called by muse, mutect2, varscan2
- KCND2 | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs748236416, COSV58579105; called by muse, mutect2, varscan2
- KCNH4 | c.762T>A p.D254E | Missense Mutation (SNP) | VAF 80/139 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs1345743266, COSV52917258; called by muse, mutect2, varscan2
- KCNH5 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV59759531; called by muse, mutect2, varscan2
- KCNH7 | c.2492G>T p.C831F | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59795900; called by muse, mutect2, varscan2
- KCNJ16 | c.650G>T p.R217I | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV52252924, COSV52255809; called by muse, mutect2, varscan2
- KCNK17 | c.553C>A p.L185I | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV64685318; called by muse, mutect2, varscan2
- KCNQ2 | c.1444A>C p.K482Q (on ENST00000359125 / NM_172107.4; = p.K454Q on NM_004518.6) | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as COSV60544473; called by muse, mutect2, varscan2
- KCNT1 | c.1024G>T p.G342C (on ENST00000488444; = p.G361C on NM_020822.3) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV53701115; called by muse, mutect2, varscan2
- KCNT2 | c.3166G>T p.V1056L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV54078440; called by muse, mutect2, varscan2
- KCNV2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.105); catalogued as rs766443513, COSV66056097; called by muse, mutect2, varscan2
- KCTD19 | c.2398C>A p.P800T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58572784; called by muse, mutect2, varscan2
- KDM2B | c.351-2A>G p.X117_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV65640601; called by muse, mutect2, varscan2
- KEAP1 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50281759; called by muse, mutect2, varscan2
- KIAA1210 | c.3473C>A p.A1158D | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV68177074; called by muse, mutect2, varscan2
- KIAA1210 | c.2113C>A p.Q705K | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV68177078; called by muse, mutect2, varscan2
- KIAA1549L | c.3511C>A p.P1171T (on ENST00000321505; = p.P1468T on NM_012194.3) | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55773405, COSV55776193; called by muse, mutect2, varscan2
- KIAA2013 | c.1265A>T p.Q422L | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV64860621; called by muse, mutect2, varscan2
- KIF21A | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.293); catalogued as rs778178203, COSV62771111; called by muse, mutect2, varscan2
- KIF2B | c.1660C>A p.H554N | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT tolerated (0.53); PolyPhen benign (0.031); catalogued as COSV52130208; called by muse, mutect2, varscan2
- KIR3DL1 | c.1276A>T p.I426F | Missense Mutation (SNP) | VAF 261/492 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV58490556, COSV58493310; called by muse, mutect2, varscan2
- KLC1 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.93); catalogued as COSV55807855; called by muse, mutect2, varscan2
- KLF3 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54710695; called by muse, mutect2, varscan2
- KLF4 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV65928907; called by muse, varscan2
- KLHDC10 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV59051598; called by muse, mutect2, varscan2
- KLHL14 | c.1390C>A p.H464N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63832303; called by muse, mutect2, varscan2
- KRT16 | c.1108A>T p.M370L | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV56967946; called by muse, mutect2, varscan2
- KRT19 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0.02); catalogued as rs748836644, COSV64238430; called by muse, mutect2, varscan2
- KRT31 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52435003; called by muse, mutect2, varscan2
- KRT31 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV52435020; called by muse, mutect2, varscan2
- KRT34 | c.959C>A p.T320K | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs1271233322, COSV67449792; called by muse, mutect2, varscan2
- KRTAP1-1 | c.103T>C p.C35R | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV60398295; called by muse, mutect2, varscan2
- KSR2 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs747557790, COSV56672047; called by muse, mutect2, varscan2
- LACC1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV57829082; called by muse, mutect2, varscan2
- LACTB2 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV52567751, COSV52568290; called by muse, mutect2, varscan2
- LAIR1 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57307433; called by muse, mutect2, varscan2
- LAMA4 | c.1673C>A p.A558E (on ENST00000230538 / NM_001105206.3; = p.A551E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.2); PolyPhen benign (0.385); catalogued as rs137893207, COSV57896467, COSV57897455; called by muse, mutect2, varscan2
- LAMB2 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.56); PolyPhen benign (0.435); catalogued as COSV59733307; called by muse, mutect2, varscan2
- LAMB4 | c.3025G>T p.G1009C | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52718524; called by muse, mutect2, varscan2
- LAMC3 | c.2131C>A p.Q711K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV63090970; called by muse, mutect2, varscan2
- LAMC3 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63089443, COSV63090977; called by muse, mutect2, varscan2
- LAYN | c.131G>T p.G44V (on ENST00000375615 / NM_001258390.1; = p.G36V on NM_178834.5) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65104799; called by muse, mutect2, varscan2
- LCOR | c.2922G>C p.Q974H | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53715732; called by muse, mutect2, varscan2
- LCT | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 80/89 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV51466232, COSV51469933; called by muse, mutect2, varscan2
- LEPR | c.1798G>T p.V600F | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60754089; called by muse, mutect2, varscan2
- LHFPL3 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV67810915; called by muse, mutect2
- LHFPL6 | c.56G>T p.C19F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV65445687; called by muse, mutect2, varscan2
- LHX9 | c.651C>A p.N217K | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as rs576950776, COSV61326713, COSV61328597; called by muse, mutect2, varscan2
- LILRB2 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1288242278, COSV58744291; called by muse, mutect2, varscan2
- LIPH | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287841272, COSV56184265; called by muse, mutect2
- LLGL2 | c.2216G>T p.G739V | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV51351621; called by muse, mutect2, varscan2
- LRBA | c.4276A>T p.T1426S | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63954822; called by muse, mutect2, varscan2
- LRP4 | c.3713C>T p.A1238V | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as COSV66135704; called by muse, mutect2, varscan2
- LRRC19 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66259471; called by muse, mutect2, varscan2
- LRRC30 | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV67301671; called by muse, mutect2, varscan2
- LRRC7 | c.3145G>C p.G1049R (on ENST00000651989 / NM_001370785.2; = p.G1016R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as COSV50545164, COSV99229428; called by muse, mutect2, varscan2
- LRRC7 | c.3146G>T p.G1049V (on ENST00000651989 / NM_001370785.2; = p.G1016V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.639); catalogued as COSV99229430; called by muse, mutect2, varscan2
- LRRIQ1 | c.2632G>T p.G878C | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67830329; called by muse, mutect2, varscan2
- LRRIQ1 | c.3317G>A p.C1106Y | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs935726809, COSV67830335; called by muse, mutect2, varscan2
- LRRN2 | c.1108C>A p.P370T | Missense Mutation (SNP) | VAF 40/54 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65783722, COSV65784532; called by muse, mutect2, varscan2
- LTBP1 | c.4130G>T p.G1377V (on ENST00000404816 / NM_206943.4; = p.G1051V on NM_000627.4) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55379047, COSV55382330; called by muse, mutect2, varscan2
- LTBP1 | c.4790G>T p.S1597I (on ENST00000404816 / NM_206943.4; = p.S1271I on NM_000627.4) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs989504771, COSV55379061; called by muse, mutect2, varscan2
- LY86 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57911928; called by muse, mutect2, varscan2
- LZTS3 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs777367896, COSV61277750; called by muse, varscan2
- MAB21L1 | c.498C>A p.Y166* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as COSV59779842, COSV59782064; called by muse, mutect2, varscan2
- MAGEA4 | c.650C>A p.A217D | Missense Mutation (SNP) | VAF 160/245 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52341203; called by muse, mutect2, varscan2
- MAGED2 | c.1085+1G>T p.X362_splice | Splice Site (SNP) | VAF 11/15 reads (73%) | catalogued as COSV54497807; called by muse, mutect2, varscan2
- MAGEE1 | c.1991C>A p.T664N | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV63909392, COSV63910130; called by muse, mutect2, varscan2
- MAGEE2 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 43/79 reads (54%) | catalogued as COSV64897690; called by muse, mutect2, varscan2
- MAGEL2 | c.2165G>T p.R722M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV58566908; called by muse, mutect2, varscan2
- MAGT1 | c.800C>T p.A267V (on ENST00000618282 / NM_001367916.1; = p.A299V on NM_032121.5) | Missense Mutation (SNP) | VAF 84/148 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.116); catalogued as COSV63781598; called by muse, mutect2, varscan2
- MAN1B1 | c.515C>A p.P172H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as COSV63034964; called by muse, mutect2, varscan2
- MAP7D3 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV60170873; called by muse, mutect2, varscan2
- MAPK1 | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53186330, COSV99308013; called by muse, mutect2, varscan2
- MBNL3 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs761100249, COSV63730833; called by muse, varscan2
- MED12 | c.4261G>T p.E1421* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV61331302, COSV61339341; called by muse, varscan2
- MED12 | c.4342G>T p.G1448W | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61339360, COSV61350212; called by muse, varscan2
- MED12L | c.6362G>T p.R2121L | Missense Mutation (SNP) | VAF 67/77 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV56378084; called by muse, mutect2, varscan2
- MEPCE | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52769173; called by muse, mutect2, varscan2
- MGAM | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 111/125 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71884977; called by muse, mutect2, varscan2
- MIB1 | c.531G>A p.K177= | Splice Region (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55090305; called by muse, mutect2, varscan2
- MICAL2 | c.3083G>T p.R1028L | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV56319824, COSV56320107; called by muse, mutect2, varscan2
- MIIP | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52427613; called by muse, mutect2, varscan2
- MINAR1 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100549205; called by muse, mutect2, varscan2
- MIPEP | c.1234G>T p.V412L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV66300509; called by muse, mutect2, varscan2
- MLIP | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.242); catalogued as COSV51429536; called by muse, mutect2, varscan2
- MMP7 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52772048; called by muse, mutect2, varscan2
- MMP8 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52632433; called by muse, mutect2, varscan2
- MORF4L1 | c.1057_1058insT p.A353Vfs*4 (on ENST00000331268 / NM_206839.2; = p.A314Vfs*4 on NM_006791.4) | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as COSV100489200; called by mutect2, pindel, varscan2
- MRE11 | c.1575G>T p.R525S | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.149); catalogued as COSV60576669; called by muse, mutect2, varscan2
- MROH5 | c.2771C>A p.P924H | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as COSV71301452; called by muse, mutect2, varscan2
- MS4A7 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); catalogued as COSV55729350, COSV55729802; called by muse, mutect2, varscan2
- MTUS2 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as COSV70916711; called by muse, mutect2, varscan2
- MUC16 | c.20713C>A p.L6905I | Missense Mutation (SNP) | VAF 85/111 reads (77%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.246); catalogued as COSV67464227; called by muse, mutect2, varscan2
- MUC16 | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV67464235; called by muse, mutect2, varscan2
- MUC17 | c.3541T>A p.S1181T | Missense Mutation (SNP) | VAF 298/743 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV60287876; called by muse, mutect2, varscan2
- MUC17 | c.4241G>C p.S1414T | Missense Mutation (SNP) | VAF 135/541 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV60287882; called by muse, mutect2, varscan2
- MUC17 | c.12403T>A p.C4135S | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1407889551, COSV60287888; called by muse, mutect2, varscan2
- MUC3A | c.8694C>A p.S2898R | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.148); catalogued as rs775226166, COSV60215029; called by muse, mutect2
- MYCBP2 | c.5420G>A p.G1807E (on ENST00000357337; = p.G1845E on NM_015057.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1253609420, COSV62018156; called by muse, mutect2, varscan2
- MYH3 | c.5747C>T p.S1916F | Missense Mutation (SNP) | VAF 32/38 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV56864714; called by muse, mutect2, varscan2
- MYH3 | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 75/87 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV56864725; called by muse, mutect2, varscan2
- MYLIP | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV62766721; called by muse, mutect2, varscan2
- MYO3A | c.2834A>T p.Q945L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV56329905; called by muse, mutect2, varscan2
- MYO7B | c.1481C>A p.P494H | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV101268370; called by muse, mutect2, varscan2
- MYO9A | c.2911C>T p.R971* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs374172306; called by muse, mutect2
- MYOM1 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1469273612, COSV55291367; called by muse, mutect2, varscan2
- MYOM2 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV50711292; called by muse, mutect2, varscan2
- MYT1 | c.2735G>T p.R912M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60505520; called by muse, mutect2, varscan2
- MYT1L | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as COSV67719527; called by muse, mutect2, varscan2
- NAA35 | c.2085G>T p.K695N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV64484776; called by muse, mutect2, varscan2
- NALCN | c.41C>A p.P14Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV99217365; called by muse, mutect2, varscan2
- NAPEPLD | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 31/105 reads (30%) | catalogued as COSV58522197; called by muse, mutect2, varscan2
- NBAS | c.6311G>T p.R2104L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV55720842, COSV99029338, COSV99870509; called by muse, mutect2, varscan2
- NDN | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100086701, COSV59359657; called by muse, mutect2, varscan2
- NDUFAF5 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.316); catalogued as COSV65246921, COSV65247473; called by muse, mutect2, varscan2
- NEB | c.3424G>T p.D1142Y | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50900549, COSV51370440; called by muse, mutect2, varscan2
- NEK10 | c.2689G>T p.D897Y | Missense Mutation (SNP) | VAF 54/65 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55358290; called by muse, mutect2, varscan2
- NELL2 | c.2260C>A p.R754S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV61574298; called by muse, mutect2, varscan2
- NES | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV63960986; called by muse, mutect2
- NETO1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55006278, COSV55006818; called by muse, mutect2, varscan2
- NEURL2 | c.742+1G>C p.X248_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99510122; called by muse, mutect2, varscan2
- NEXMIF | c.1049C>A p.S350Y | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV50030082; called by muse, mutect2, varscan2
- NF1 | c.3845G>T p.S1282I | Missense Mutation (SNP) | VAF 81/135 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62202528; called by muse, mutect2, varscan2
- NF1 | c.5018A>G p.N1673S (on ENST00000358273 / NM_001042492.3; = p.N1652S on NM_000267.3) | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.984); catalogued as rs1201910133, COSV55985972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFASC | c.2750C>A p.P917Q (on ENST00000339876 / NM_001378329.1; = p.P1020Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV58365070; called by muse, mutect2, varscan2
- NFATC2 | c.2672G>T p.G891V | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV65355659; called by muse, mutect2, varscan2
- NFYA | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV58198543; called by muse, mutect2, varscan2
- NHSL2 | c.1581G>T p.E527D (on ENST00000510661; = p.E893D on NM_001013627.2) | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV65453346, COSV65455363; called by muse, mutect2
- NIPAL4 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57429627; called by muse, mutect2, varscan2
- NKX2-2 | c.65A>T p.N22I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV65819513; called by muse, mutect2, varscan2
- NLRC4 | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61592573; called by muse, mutect2, varscan2
- NLRP1 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 68/85 reads (80%) | catalogued as COSV52565727; called by muse, mutect2, varscan2
- NLRP12 | c.3134G>C p.S1045T | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV60747118; called by muse, mutect2, varscan2
- NLRP4 | c.1406A>T p.H469L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); catalogued as COSV56713198; called by muse, mutect2, varscan2
- NME5 | c.137A>T p.K46I | Missense Mutation (SNP) | VAF 16/16 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV54522753; called by muse, mutect2, varscan2
- NOBOX | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as COSV56193195, COSV56194228; called by muse, mutect2, varscan2
- NPAP1 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.618); catalogued as COSV61506719; called by muse, mutect2, varscan2
- NPAP1 | c.1613C>A p.T538N | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV61506729; called by muse, mutect2, varscan2
- NPAS4 | c.601C>A p.P201T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60650352; called by muse, varscan2
- NPHS2 | c.1091C>A p.P364Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV100858204, COSV62635214, COSV62636715; called by muse, mutect2, varscan2
- NPIPA1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV60154246; called by mutect2, varscan2
- NPR3 | c.1276G>C p.A426P | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as COSV54087429, COSV54090021; called by muse, mutect2, varscan2
- NPR3 | c.1465G>T p.V489L (on ENST00000265074 / NM_001364458.2; = p.V488L on NM_000908.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.988); catalogued as rs542365419, COSV54087446; called by muse, mutect2, varscan2
- NPY1R | c.892C>G p.H298D | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56714405; called by muse, mutect2, varscan2
- NPY2R | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV61527228, COSV61528234; called by muse, mutect2, varscan2
- NRAP | c.3736C>T p.H1246Y (on ENST00000359988 / NM_001322945.2; = p.H1211Y on NM_006175.4) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63490479; called by muse, mutect2, varscan2
- NRCAM | c.331G>T p.E111* (on ENST00000379028 / NM_001371124.1; = p.E105* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as COSV61036331; called by muse, mutect2, varscan2
- NRXN2 | c.3920A>T p.Q1307L | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV55452769; called by muse, mutect2, varscan2
- NSUN2 | c.388A>G p.N130D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV104391228, COSV52954170; called by muse, mutect2, varscan2
- NTRK3 | c.1485T>G p.D495E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV58121015; called by muse, mutect2, varscan2
- NWD1 | c.4493G>T p.R1498L | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV100343583, COSV60344240; called by muse, mutect2, varscan2
- OAS1 | c.752C>A p.T251K | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52535621; called by muse, mutect2, varscan2
- ODF2 | c.2486C>G p.A829G (on ENST00000434106 / NM_153433.2; = p.A805G on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV59407614; called by muse, mutect2, varscan2
- OGT | c.2495G>T p.R832L | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV101035114, COSV65480706; called by muse, mutect2, varscan2
- OLFML2B | c.265T>A p.C89S | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV54196200; called by muse, mutect2, varscan2
- OLIG3 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62988550; called by muse, mutect2, varscan2
- OOEP | c.298C>G p.P100A | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV64859090, COSV64859208; called by muse, mutect2, varscan2
- OR10AG1 | c.905G>C p.*302Sext*9 | Nonstop Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100400186; called by muse, mutect2, varscan2
- OR10K1 | c.603G>T p.M201I | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56871767; called by muse, mutect2, varscan2
- OR10S1 | c.648C>A p.S216R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV73342782; called by muse, mutect2, varscan2
- OR10T2 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV57781175; called by muse, mutect2, varscan2
- OR10W1 | c.445C>G p.Q149E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.76); catalogued as COSV67720412; called by muse, mutect2, varscan2
- OR13C8 | c.74C>G p.T25R | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58611107; called by muse, mutect2, varscan2
- OR1C1 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as COSV68715716; called by muse, mutect2, varscan2
- OR1S1 | c.937G>C p.A313P | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58707046; called by muse, mutect2, varscan2
- OR2L13 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 93/113 reads (82%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as COSV63552561; called by muse, mutect2, varscan2
- OR2T34 | c.341del p.G114Efs*27 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as COSV60902032; called by mutect2, varscan2
- OR4A5 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.918); catalogued as COSV60522460; called by muse, mutect2, varscan2
- OR4C15 | c.156G>T p.L52F | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV58952708, COSV58953821; called by muse, mutect2, varscan2
- OR4C6 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58603783; called by muse, mutect2, varscan2
- OR4C6 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58603793; called by muse, mutect2, varscan2
- OR4D9 | c.666G>C p.L222F | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV61434621; called by muse, mutect2, varscan2
- OR4K13 | c.774C>A p.Y258* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV59859418, COSV59859564; called by muse, mutect2, varscan2
- OR4K15 | c.706C>A p.L236I (on ENST00000305051; = p.L212I on NM_001005486.1) | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0.034); catalogued as COSV100521184, COSV59300336; called by muse, mutect2, varscan2
- OR4S1 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs185370970, COSV100180201, COSV100180333; called by muse, mutect2, varscan2
- OR5D14 | c.29T>A p.M10K | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100162081, COSV100162577; called by muse, mutect2, varscan2
- OR5D14 | c.30G>T p.M10I | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100162579, COSV59458809; called by muse, mutect2, varscan2
- OR5K1 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 87/94 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1032366530, COSV60304126; called by muse, mutect2, varscan2
- OR5K4 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 311/347 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61583748; called by muse, mutect2, varscan2
- OR5K4 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 75/83 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61583757; called by muse, mutect2, varscan2
- OR5L2 | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1000778154, COSV65723979; called by muse, mutect2, varscan2
- OR5T3 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.707); catalogued as COSV57380493; called by muse, varscan2
- OR5T3 | c.758G>C p.C253S | Missense Mutation (SNP) | VAF 69/120 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57380504; called by muse, varscan2
- OR6K2 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1366231424, COSV62743436; called by muse, mutect2, varscan2
- OR6N1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV58647402, COSV58648319; called by muse, mutect2, varscan2
- OR9Q2 | c.790A>T p.T264S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61111873; called by muse, mutect2, varscan2
- ORMDL3 | c.286A>T p.T96S | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV58345844; called by muse, mutect2, varscan2
- OTUD7A | c.1174G>A p.V392M (on ENST00000307050 / NM_001382637.1; = p.V385M on NM_130901.3) | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774039859, COSV61038511; called by muse, mutect2, varscan2
- P2RY2 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs765341118, COSV100232852; called by muse, mutect2, varscan2
- PADI6 | c.444G>C p.W148C | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100639965, COSV61884539; called by muse, mutect2, varscan2
- PALLD | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54980065; called by muse, mutect2, varscan2
- PAPPA2 | c.4346C>G p.S1449C | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV62797066, COSV62806904; called by muse, mutect2, varscan2
- PARD3B | c.2326G>T p.G776C (on ENST00000406610 / NM_001302769.2; = p.G714C on NM_152526.6) | Missense Mutation (SNP) | VAF 68/84 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62510651; called by muse, mutect2, varscan2
- PATZ1 | c.44A>G p.Y15C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs757918024, COSV53229310; called by muse, mutect2, varscan2
- PC | c.2908G>A p.D970N | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.509); catalogued as COSV58992650; called by muse, mutect2, varscan2
- PCDH11X | c.2456C>A p.A819D | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53463509; called by muse, mutect2, varscan2
- PCDH11X | c.2723C>G p.P908R | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53463546; called by muse, mutect2, varscan2
- PCDH11X | c.3538G>T p.A1180S | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV53463587; called by muse, mutect2, varscan2
- PCDH17 | c.3250C>A p.Q1084K | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.054); catalogued as COSV64973834; called by muse, mutect2, varscan2
- PCDH18 | c.2943G>C p.K981N | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV61268281; called by muse, mutect2, varscan2
- PCDH8 | c.2882C>G p.S961C | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58812539; called by muse, mutect2, varscan2
- PCDHA2 | c.769_770insT p.N257Ifs*7 | Frame Shift Ins (INS) | VAF 26/46 reads (57%) | catalogued as COSV100974128; called by mutect2, pindel, varscan2
- PCDHA6 | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV65343947; called by muse, mutect2, varscan2
- PCDHB11 | c.1606C>A p.R536S | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.283); catalogued as COSV100697126, COSV61311492, COSV61312515; called by muse, mutect2, varscan2
- PCDHB11 | c.2006C>A p.P669H | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV61311501; called by muse, mutect2, varscan2
- PCDHB12 | c.2359C>T p.P787S | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1420165730, COSV53393585; called by muse, mutect2, varscan2
- PCDHB13 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.086); catalogued as COSV53396388, COSV53401731; called by muse, mutect2, varscan2
- PCDHB3 | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 30/40 reads (75%) | catalogued as COSV50572225; called by muse, varscan2
- PCDHB9 | c.2032C>A p.P678T | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV53378520; called by muse, mutect2, varscan2
- PCDHGA4 | c.1873G>T p.V625L | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as COSV53943747; called by muse, mutect2, varscan2
- PCDHGB3 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53943762, COSV54018998; called by muse, mutect2, varscan2
- PCIF1 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59817606; called by muse, varscan2
- PCLO | c.15392G>T p.W5131L | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61627259; called by muse, mutect2, varscan2
- PCLO | c.9622G>T p.D3208Y | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV61633777; called by muse, mutect2, varscan2
- PDCD11 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV58915658; called by muse, mutect2, varscan2
- PDE1C | c.426-2A>T p.X142_splice | Splice Site (SNP) | VAF 11/33 reads (33%) | catalogued as COSV58513138; called by muse, mutect2, varscan2
- PDE3A | c.3078G>A p.W1026* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as COSV62972476; called by muse, mutect2, varscan2
- PDILT | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV56701795; called by muse, mutect2, varscan2
- PEAK1 | c.4849G>T p.E1617* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV56934935; called by muse, mutect2, varscan2
- PEX6 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55102965; called by muse, mutect2, varscan2
- PGM5 | c.1669A>G p.R557G | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV67167566; called by muse, mutect2, varscan2
- PHF2 | c.2303T>G p.L768R | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63680818; called by muse, mutect2, varscan2
- PHF3 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV50318310; called by muse, mutect2, varscan2
- PI3 | c.100del p.T34Lfs*47 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as CM099561; called by mutect2, pindel, varscan2
- PIAS4 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV99519038; called by muse, mutect2, varscan2
- PIK3C2G | c.2672A>T p.D891V (on ENST00000676171; = p.D850V on NM_004570.5) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV56808187; called by muse, mutect2
- PINX1 | c.833G>T p.G278V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs757948941, COSV59109162; called by muse, mutect2, varscan2
- PIP4P1 | c.812A>T p.H271L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV51657653, COSV51659019; called by muse, mutect2, varscan2
- PKD1L2 | c.851T>A p.L284Q | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61415083; called by muse, mutect2, varscan2
- PKHD1 | c.11425G>T p.G3809C | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV64389484; called by muse, mutect2, varscan2
- PKIG | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV63068894; called by muse, mutect2, varscan2
- PLA2G4F | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.57); catalogued as rs375162581; called by muse, mutect2, varscan2
- PLB1 | c.4013C>A p.T1338N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.291); catalogued as COSV59824611; called by muse, mutect2, varscan2
- PLCB1 | c.2312A>T p.Y771F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as COSV62049509; called by mutect2, varscan2
- PLIN2 | c.104G>T p.S35I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99439145; called by muse, mutect2, varscan2
- PLIN2 | c.103A>T p.S35C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV99439158; called by muse, mutect2, varscan2
- PLPP4 | c.382T>A p.C128S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64827811; called by muse, mutect2, varscan2
- PLPPR4 | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64565673; called by muse, mutect2, varscan2
- PLXDC2 | c.1360G>T p.A454S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as COSV65903626; called by muse, mutect2, varscan2
- PLXNA1 | c.5250G>T p.W1750C | Missense Mutation (SNP) | VAF 69/76 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52525850; called by muse, mutect2, varscan2
- PLXNC1 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51574949; called by muse, varscan2
- PMFBP1 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV52822001, COSV52823756; called by muse, mutect2, varscan2
- PNLIPRP2 | c.246C>A p.N82K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV53943729; called by muse, mutect2, varscan2
- POLE | c.2294G>T p.R765L | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267422, COSV57679936; called by muse, mutect2, varscan2
- PON2 | c.683del p.S228Yfs*26 | Frame Shift Del (DEL) | VAF 32/145 reads (22%) | catalogued as COSV56000865; called by mutect2, pindel, varscan2
- PPEF2 | c.9C>A p.S3R | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV54422289; called by muse, mutect2, varscan2
- PPIG | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 86/95 reads (91%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53643018; called by muse, mutect2, varscan2
- PPP1R12B | c.2145+1G>T p.X715_splice | Splice Site (SNP) | VAF 19/20 reads (95%) | catalogued as COSV51784536; called by muse, mutect2, varscan2
- PPP1R3A | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52881960; called by muse, mutect2, varscan2
- PPP2R1A | c.1622C>G p.A541G | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV59044192; called by muse, mutect2, varscan2
- PPP3R1 | c.183A>G p.I61M | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52246275; called by muse, mutect2, varscan2
- PRDM9 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV99691146; called by muse, mutect2, varscan2
- PRDM9 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV99691150; called by muse, mutect2, varscan2
- PRKCB | c.1550C>A p.P517H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57778554; called by muse, mutect2, varscan2
- PRKCG | c.1380C>A p.Y460* | Nonsense Mutation (SNP) | VAF 30/44 reads (68%) | catalogued as COSV54723632, COSV54727512; called by muse, mutect2, varscan2
- PRUNE2 | c.1537G>T p.A513S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV65041321; called by muse, mutect2
- PRX | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 119/237 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs748737580, COSV52529750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSKH2 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.27); PolyPhen benign (0.19); catalogued as rs567670091, COSV52610382; called by muse, varscan2
- PSMD7 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV54697614; called by muse, mutect2, varscan2
- PTPN1 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65408011; called by muse, mutect2, varscan2
- PTPRD | c.5536G>A p.A1846T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs141403124; called by muse, varscan2
- PTPRN | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV55346085, COSV55347749; called by muse, mutect2, varscan2
- PTPRT | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as rs375946335; called by muse, mutect2, varscan2
- PXDN | c.3412G>T p.E1138* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as rs1558488289, COSV53233323; called by muse, mutect2, varscan2
- PXDNL | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as COSV62486826; called by muse, varscan2
- PXDNL | c.3623G>C p.G1208A | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62486830; called by muse, mutect2, varscan2
- PXDNL | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62486836; called by muse, mutect2, varscan2
- PYHIN1 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV63722359; called by muse, mutect2, varscan2
- RAB30 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 48/82 reads (59%) | catalogued as COSV52626588; called by muse, mutect2, varscan2
- RAB30 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV52626598; called by muse, mutect2, varscan2
- RAB3IL1 | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV57117501; called by muse, mutect2, varscan2
- RAB3IP | c.1114G>A p.E372K (on ENST00000550536 / NM_175623.4; = p.E356K on NM_022456.5) | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV56083386; called by muse, mutect2, varscan2
- RAG1 | c.144A>T p.E48D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.057); catalogued as COSV55025114; called by muse, mutect2, varscan2
- RAG1 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs147203889, COSV55025121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RALGPS2 | c.560G>T p.R187I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61336999; called by muse, mutect2, varscan2
- RANBP3L | c.782C>A p.S261Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.174); catalogued as COSV56955497; called by muse, mutect2, varscan2
- RANBP6 | c.2918dup p.N973Kfs*19 | Frame Shift Ins (INS) | VAF 21/43 reads (49%) | catalogued as rs746880803; called by mutect2, varscan2
- RANGAP1 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.161); catalogued as COSV62363390; called by muse, mutect2, varscan2
- RAPGEF3 | c.481G>T p.D161Y (on ENST00000389212; = p.D119Y on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50205343; called by muse, mutect2, varscan2
- RASA3 | c.174-2A>T p.X58_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV61866993; called by muse, mutect2, varscan2
- RBFOX1 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV60957715, COSV60957848; called by muse, mutect2, varscan2
- RBM19 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55691812; called by muse, mutect2, varscan2
- REG3A | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV59409489, COSV59412525; called by muse, mutect2, varscan2
- RELN | c.8027G>A p.S2676N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV59000599; called by muse, mutect2, varscan2
- RELN | c.6058A>G p.I2020V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs765511963, COSV59000609; called by muse, mutect2, varscan2
- RELN | c.2443T>G p.Y815D | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV59000627; called by muse, mutect2, varscan2
- RELN | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59000641; called by muse, varscan2
- REM1 | c.82C>G p.H28D | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV52428101; called by muse, mutect2, varscan2
- RGS12 | c.3736G>C p.A1246P | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.33); PolyPhen benign (0.38); catalogued as COSV58751508; called by muse, mutect2, varscan2
- RIF1 | c.4010G>A p.C1337Y | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); catalogued as rs766688897, COSV54616875, COSV54617110; called by muse, mutect2, varscan2
- RIMBP2 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as rs776284629, COSV55471826; called by muse, mutect2, varscan2
- RIMS1 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 14/18 reads (78%) | catalogued as COSV53454403; called by muse, mutect2, varscan2
- RLIM | c.1743C>A p.N581K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60326358; called by muse, mutect2, varscan2
- RNF157 | c.1726A>C p.N576H | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV53943994; called by muse, mutect2, varscan2
- RNF17 | c.3707C>A p.A1236E | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55040093; called by muse, mutect2, varscan2
- RNF20 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); catalogued as rs778771772, COSV66660861; called by muse, mutect2, varscan2
- ROCK1 | c.3496A>G p.M1166V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs748810091, COSV67695919; called by muse, mutect2
- RPE65 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV52015697; called by muse, mutect2, varscan2
- RPH3A | c.268G>T p.V90L (on ENST00000389385 / NM_001143854.2; = p.V86L on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/78 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV66990987; called by muse, varscan2
- RPH3A | c.640C>G p.Q214E (on ENST00000389385 / NM_001143854.2; = p.Q210E on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV66990991; called by muse, mutect2, varscan2
- RPLP1 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV53006522; called by muse, mutect2, varscan2
- RPS6KA6 | c.979C>T p.H327Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV53119499; called by muse, mutect2
- RPS6KA6 | c.194A>T p.Y65F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV53119508; called by muse, mutect2, varscan2
- RPTN | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as rs946818007, COSV100285910, COSV60167216; called by muse, mutect2, varscan2
- RTN4R | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV50381171, COSV99245070; called by muse, mutect2, varscan2
- RUNX1T1 | c.558+2T>C p.X186_splice (on ENST00000265814 / NM_001198628.1; = p.X159_splice on NM_004349.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV56142838, COSV56148679; called by muse, mutect2, varscan2
- RXFP2 | c.845C>A p.S282* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV53635459; called by muse, mutect2, varscan2
- RYR1 | c.14065A>G p.I4689V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1207270581, COSV62096635; called by muse, mutect2, varscan2
- SAGE1 | c.2312G>T p.S771I | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV61013246; called by muse, mutect2, varscan2
- SAMD4A | c.1556G>T p.S519I | Missense Mutation (SNP) | VAF 121/140 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV51880747; called by muse, mutect2, varscan2
- SATL1 | c.115C>T p.P39S (on ENST00000395409; = p.P226S on NM_001012980.2) | Missense Mutation (SNP) | VAF 83/140 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as COSV60576568; called by muse, mutect2, varscan2
- SCARA3 | c.1467G>C p.L489F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.361); catalogued as COSV57270137; called by muse, mutect2
- SCG2 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 74/84 reads (88%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV59539446; called by muse, mutect2, varscan2
- SCN2A | c.1887C>A p.S629R | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51840428; called by muse, mutect2, varscan2
- SCP2D1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53857260; called by muse, mutect2, varscan2
- SDR42E1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs371497769, COSV61094161; called by muse, mutect2, varscan2
- SEC61A1 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54577032, COSV54577977; called by muse, mutect2
- SEPTIN14 | c.703G>C p.A235P | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV66427529; called by muse, mutect2, varscan2
- SERPINB7 | c.214A>G p.S72G | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as COSV60533810; called by muse, mutect2, varscan2
- SERPINI1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369596299; ClinVar: likely benign; called by muse, mutect2, varscan2
- SETBP1 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV56321385, COSV56325917; called by muse, mutect2, varscan2
- SETD5 | c.4318G>C p.G1440R | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56710734; called by muse, mutect2, varscan2
- SETDB2 | c.1959T>A p.S653R | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51644392; called by mutect2, varscan2
- SHPK | c.1291G>T p.G431W | Missense Mutation (SNP) | VAF 84/99 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56649019; called by muse, mutect2, varscan2
- SIGLEC8 | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 40/81 reads (49%) | catalogued as COSV58473674; called by muse, mutect2, varscan2
- SIRPG | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.938); catalogued as rs750582002, COSV53807296; called by muse, mutect2, varscan2
- SLC12A9 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99308148; called by muse, mutect2, varscan2
- SLC17A4 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as COSV64956153; called by muse, mutect2, varscan2
- SLC22A16 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57929665; called by muse, mutect2, varscan2
- SLC22A25 | c.1631G>T p.S544I | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs776976900, COSV60595624, COSV60596640; called by muse, mutect2, varscan2
- SLC25A30 | c.561G>T p.K187N | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60433780; called by muse, mutect2, varscan2
- SLC2A9 | c.821A>G p.Q274R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV53320232; called by muse, mutect2, varscan2
- SLC30A8 | c.7T>A p.F3I | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as COSV69970377; called by muse, mutect2, varscan2
- SLC34A1 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.93); catalogued as COSV60996697; called by muse, mutect2, varscan2
- SLC38A10 | c.3274C>T p.Q1092* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV66101259; called by muse, mutect2, varscan2
- SLC38A8 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as COSV55306377, COSV55307088; called by muse, mutect2, varscan2
- SLC43A1 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53558797; called by muse, mutect2, varscan2
- SLC4A3 | c.2537T>G p.V846G | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV56093576; called by muse, mutect2, varscan2
- SLC6A1 | c.183del p.I62Sfs*22 | Frame Shift Del (DEL) | VAF 28/44 reads (64%) | catalogued as COSV55118425; called by mutect2, pindel, varscan2
- SLC6A18 | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57251175; called by muse, mutect2, varscan2
- SLFN12 | c.1652C>T p.A551V | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV59225840; called by muse, mutect2, varscan2
- SLFN5 | c.2140A>T p.N714Y | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV55481040; called by muse, mutect2, varscan2
- SLITRK2 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as COSV59425251, COSV59428776; called by muse, mutect2, varscan2
- SLITRK3 | c.2495C>T p.T832M | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs745603572, COSV53848285; called by muse, mutect2, varscan2
- SLITRK5 | c.2091C>A p.S697R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV61521683, COSV61522764; called by muse, mutect2, varscan2
- SMARCA1 | c.1832T>G p.I611S | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64411860; called by muse, mutect2, varscan2
- SMARCA1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.292); catalogued as COSV64411870; called by muse, mutect2, varscan2
- SMARCA5 | c.2942C>T p.P981L | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV51644232; called by muse, mutect2, varscan2
- SND1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV61240464, COSV61249718; called by muse, mutect2, varscan2
- SNTG2 | c.906G>T p.W302C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57981000; called by muse, mutect2
- SNX15 | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57246623; called by muse, mutect2, varscan2
- SNX9 | c.1204G>T p.V402L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV67584102; called by muse, mutect2, varscan2
- SOCS2 | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61392155; called by muse, mutect2, varscan2
- SORCS1 | c.1174G>T p.V392L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53864499; called by muse, mutect2, varscan2
- SORCS1 | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53864515; called by muse, mutect2, varscan2
- SORCS3 | c.996G>T p.M332I | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV63809703; called by muse, varscan2
- SORCS3 | c.3509C>G p.S1170* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV63809707; called by muse, mutect2, varscan2
- SPATA19 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54483255; called by muse, mutect2, varscan2
- SPHKAP | c.3850G>T p.G1284C | Missense Mutation (SNP) | VAF 39/45 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60877867; called by muse, mutect2, varscan2
- SPHKAP | c.2734G>C p.A912P | Missense Mutation (SNP) | VAF 112/129 reads (87%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.462); catalogued as rs770613357, COSV60877887; called by muse, mutect2, varscan2
- SPRY3 | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57142845; called by muse, mutect2, varscan2
- SPTA1 | c.6710G>T p.G2237V | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63752722, COSV63757175; called by muse, mutect2, varscan2
- SRCAP | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs778348276, COSV52672270; called by muse, mutect2, varscan2
- SRI | c.511+1G>T p.X171_splice | Splice Site (SNP) | VAF 35/67 reads (52%) | catalogued as COSV56000735; called by muse, mutect2, varscan2
- SRPX | c.428G>T p.C143F | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59438555; called by muse, mutect2, varscan2
- SRSF4 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65694575; called by muse, mutect2, varscan2
- SSH1 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs767419477, COSV58455402, COSV58456338; called by muse, mutect2, varscan2
- SSH2 | c.3870G>C p.Q1290H | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); catalogued as COSV52171933; called by muse, mutect2, varscan2
- STC2 | c.635C>A p.T212N | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV99438653; called by muse, mutect2, varscan2
- STK26 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 40/112 reads (36%) | catalogued as COSV61229734; called by muse, mutect2, varscan2
- STRIP2 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50804138; called by muse, mutect2, varscan2
- SUMO2 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV58813459; called by muse, mutect2, varscan2
- SUN1 | c.869-2A>T p.X290_splice (on ENST00000405266 / NM_001367651.1; = p.X170_splice on NM_025154.6 and 13 other RefSeq transcripts) | Splice Site (SNP) | VAF 23/58 reads (40%) | catalogued as COSV61778193; called by muse, mutect2, varscan2
- SUSD1 | c.2013A>G p.I671M | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV62583527; called by muse, mutect2, varscan2
- SV2A | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV64964135, COSV64964693, COSV64965690; called by muse, mutect2, varscan2
- SYN1 | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as COSV55981383; called by mutect2, varscan2
- SYN2 | c.1730C>A p.A577D | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748815864, COSV70285297; called by muse, mutect2, varscan2
- SYNE2 | c.1626T>A p.C542* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as COSV59950201; called by muse, mutect2, varscan2
443 further variants in this file (169 protein-altering or splice-affecting, 249 silent, 25 other) are not listed here.
